RC case RC-B6SL — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c0529ad4-c4d3-4d94-bb27-2bac45e25e89

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1957; Vital status: Dead; Days to death: 528 days (1.4 years); Year of death: 2011; Country of birth: United States.

Diagnoses (1)
1. Peripheral T-cell lymphoma, NOS: ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of multiple regions; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,144 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Weight Loss; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Iliac-Common / Lymph Node, Iliac-External / Lymph Node, Mediastinal / Lymph Node, Para-Aortic.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 4.9 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CEOP; Days to treatment start: 37 days; Days to treatment end: 198 days; Number of cycles: 5; Reason treatment ended: Other; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100.
- Days to follow up: 177 days; Disease response: Tumor Free.
- Days to follow up: 198 days; Disease response: With Tumor.
- Follow-up contacts recording only the day: day 528, last contact.

Molecular and laboratory tests
- Lactate Dehydrogenase 265 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 98 kg; Height: 191 cm; BMI: 26.9.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 13; Tobacco smoking onset year: 1995.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SL-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SL-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SL-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
